Somatic mutation profile of tumor specimen TCGA-CU-A72E-01A (aliquot TCGA-CU-A72E-01A-12D-A339-08) from TCGA case TCGA-CU-A72E, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 76.6 years (27,963 days).
Specimen TCGA-CU-A72E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e08e171d-851d-41d9-a762-8c01bad28bbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CU-A72E-10A (Blood Derived Normal), aliquot TCGA-CU-A72E-10A-01D-A339-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ceea1fa7-9e46-496d-a01f-51ec3a157dc7

The open-access MAF lists 115 somatic variants for this specimen: 81 protein-altering or splice-affecting, 32 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 32, Nonsense Mutation 8, Frame Shift Del 2, Frame Shift Ins 2, Splice Site 2, 3'UTR 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DES | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs62636491, CM070891; ClinVar: likely pathogenic / uncertain significance / benign; called by muse, mutect2, varscan2
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 24/31 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADCY9 | c.3418G>A p.E1140K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs745559844, COSV53577231; called by muse, mutect2, varscan2
- AIFM2 | c.1085C>G p.S362C | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.864); catalogued as COSV57160995; called by muse, mutect2, varscan2
- AQR | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs768894484, COSV50055324; called by muse, mutect2, varscan2
- ARHGEF18 | c.1782G>T p.Q594H (on ENST00000359920 / NM_001130955.2; = p.Q490H on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV60474308; called by muse, mutect2, varscan2
- ARNTL | c.1471G>A p.G491R (on ENST00000403290 / NM_001297719.2; = p.G490R on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.741); catalogued as COSV100724491; called by muse, mutect2, varscan2
- ASPSCR1 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100144651; called by muse, mutect2, varscan2
- ATP2A3 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as rs1567695323, COSV59232277, COSV99989786; called by muse, mutect2, varscan2
- BRD2 | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as rs771087576, COSV66374550; called by muse, mutect2, varscan2
- BRD4 | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs767979123, COSV99649667; called by muse, varscan2
- CASP2 | c.553C>G p.Q185E | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV60083654; called by muse, mutect2, varscan2
- CFHR4 | c.1534A>T p.I512L (on ENST00000367416 / NM_001201551.2; = p.I266L on NM_006684.5) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.145); catalogued as COSV99259167; called by mutect2, varscan2
- CSMD1 | c.8699G>A p.C2900Y (on ENST00000520002; = p.C2899Y on NM_033225.6) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100141920; called by muse, mutect2
- CTAGE1 | c.502C>G p.Q168E | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV66945038; called by muse, mutect2, varscan2
- DISP1 | c.4355C>T p.S1452L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV52665282; called by muse, mutect2, varscan2
- DPP9 | c.2474G>T p.R825L (on ENST00000598800; = p.R854L on NM_139159.5) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99505585; called by muse, mutect2
- ELK1 | c.28T>C p.F10L | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55954676; called by muse, mutect2, varscan2
- FANCM | c.238G>C p.G80R | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53533872; called by muse, mutect2, varscan2
- FAT2 | c.7756_7764del p.K2586_S2588del | In Frame Del (DEL) | VAF 40/144 reads (28%) | catalogued as COSV55829853; called by mutect2, pindel, varscan2
- FILIP1 | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV52741217; called by muse, mutect2, varscan2
- FLNB | c.6553G>T p.V2185L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV55889464, COSV55896276; called by muse, mutect2, varscan2
- GABRA4 | c.577+1G>A p.X193_splice | Splice Site (SNP) | VAF 3/17 reads (18%) | catalogued as COSV99973273; called by muse, mutect2
- HIRA | c.1741G>T p.A581S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV54274322; called by muse, mutect2, varscan2
- ID2 | c.365C>G p.S122C | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.343); catalogued as COSV52171084; called by muse, mutect2, varscan2
- IL4I1 | c.154G>C p.G52R | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62012249; called by muse, mutect2, varscan2
- ITPR3 | c.4222G>A p.E1408K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV65415095; called by muse, mutect2, varscan2
- KCNT2 | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs775316374, COSV54099743, COSV99652419; called by muse, mutect2, varscan2
- KCNV2 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs377471498, COSV66055783; called by muse, mutect2, varscan2
- KIAA1522 | c.1417C>T p.Q473* (on ENST00000373480 / NM_001198972.2; = p.Q532* on NM_020888.3) | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV53866202, COSV99614023; called by muse, mutect2, varscan2
- KIF13A | c.3644C>T p.P1215L | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1472628107, COSV52466173; called by muse, mutect2, varscan2
- KIR3DL2 | c.638T>A p.L213Q | Missense Mutation (SNP) | VAF 132/444 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99551652; called by muse, varscan2
- KLHL41 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.974); catalogued as COSV52931532; called by muse, mutect2, varscan2
- KLK11 | c.736C>G p.Q246E (on ENST00000594768 / NM_144947.3; = p.Q214E on NM_006853.3) | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV59399556; called by muse, mutect2, varscan2
- KRT74 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs766680853, COSV59771535; called by muse, mutect2, varscan2
- KRTAP10-7 | c.398C>G p.S133C | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV59113397; called by muse, mutect2, varscan2
- LAMA2 | c.4210C>G p.Q1404E | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70355559; called by muse, mutect2, varscan2
- LAMA4 | c.5179T>C p.C1727R (on ENST00000230538 / NM_001105206.3; = p.C1720R on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57905441; called by muse, mutect2, varscan2
- LRP2 | c.7721G>A p.R2574K | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55575489; called by muse, mutect2, varscan2
- MBLAC1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs753136685, COSV53543214, COSV99498920; called by muse, mutect2, varscan2
- MED12 | c.952C>G p.H318D | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV100379415, COSV61356365; called by muse, mutect2, varscan2
- MGA | c.8211G>C p.Q2737H (on ENST00000219905 / NM_001164273.1; = p.Q2528H on NM_001080541.2) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV54949380; called by muse, mutect2, varscan2
- MYO5A | c.4872G>C p.M1624I | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV62557221, COSV62564962; called by muse, mutect2, varscan2
- OR5K1 | c.449T>C p.I150T | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV60305367, COSV60305372; called by muse, mutect2, varscan2
- PARP4 | c.3351G>C p.Q1117H | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67964318; called by muse, mutect2, varscan2
- PCLO | c.11101G>A p.E3701K | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs369294508; called by muse, mutect2, varscan2
- PDE1C | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs775393302, COSV58502926; called by muse, mutect2, varscan2
- PLRG1 | c.1183A>G p.I395V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.181); catalogued as rs770484620, COSV57424756; called by muse, mutect2, varscan2
- PNP | c.408C>G p.I136M | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64092309; called by muse, mutect2, varscan2
- POLR1G | c.984G>C p.K328N | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.263); catalogued as COSV50005579; called by muse, mutect2, varscan2
- POU4F2 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 24/56 reads (43%) | catalogued as COSV55587280, COSV99850198; called by muse, mutect2, varscan2
- PYCR2 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1239964151, COSV59525542; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBM10 | c.863C>G p.S288* | Nonsense Mutation (SNP) | VAF 3/9 reads (33%) | catalogued as COSV61310814; called by muse, mutect2
- RPS3A | c.535A>C p.N179H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.895); catalogued as COSV56839880; called by muse, mutect2, varscan2
- SACS | c.6631C>G p.Q2211E | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as rs753267159, COSV66546987; called by muse, mutect2, varscan2
- SIRT2 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs201687831, COSV50877339; called by muse, mutect2, varscan2
- SPHK2 | c.1490C>G p.S497C | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV55342380; called by muse, mutect2, varscan2
- STAG2 | c.3562G>T p.G1188* | Nonsense Mutation (SNP) | VAF 31/45 reads (69%) | catalogued as COSV99491965; called by muse, mutect2, varscan2
- SULF2 | c.2453G>A p.G818D | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59073656; called by muse, mutect2, varscan2
- TG | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 44/56 reads (79%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV55095045; called by muse, mutect2, varscan2
- TOPBP1 | c.326T>A p.V109E | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV53441922; called by muse, mutect2, varscan2
- TOPBP1 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV53441943; called by muse, mutect2, varscan2
- TPRX1 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as rs1032720398, COSV100445442; called by muse, mutect2, varscan2
- TRPC4 | c.2570C>T p.A857V (on ENST00000379705 / NM_016179.4; = p.A862V on NM_003306.3) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV59019802; called by muse, mutect2, varscan2
- TUT4 | c.626C>G p.S209* | Nonsense Mutation (SNP) | VAF 81/180 reads (45%) | catalogued as COSV99931626; called by muse, mutect2, varscan2
- UHRF1BP1 | c.204C>G p.I68M | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51960754; called by muse, mutect2, varscan2
- UTP20 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV55375421; called by muse, mutect2, varscan2
- UTP3 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99636811; called by muse, mutect2, varscan2
- ZNF236 | c.537-1G>C p.X179_splice | Splice Site (SNP) | VAF 22/44 reads (50%) | catalogued as COSV53498176; called by muse, mutect2, varscan2
- ZNF296 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV55519482; called by muse, mutect2, varscan2
- ZNF517 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV63465412; called by muse, mutect2, varscan2
- ZSWIM1 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV54851740; called by muse, mutect2, varscan2
- ZZZ3 | c.1048G>A p.G350R | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as rs368164592; called by muse, mutect2, varscan2
- ACACA | c.343A>G p.S115G | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- DHX38 | c.1366del p.E456Sfs*23 | Frame Shift Del (DEL) | VAF 25/88 reads (28%) | called by mutect2, pindel, varscan2
- ELF3 | c.1007dup p.Y336* | Nonsense Mutation (INS) | VAF 26/70 reads (37%) | called by mutect2, pindel, varscan2
- HES1 | c.432dup p.N145Qfs*70 | Frame Shift Ins (INS) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- PLPPR4 | c.905del p.K302Rfs*12 | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | called by mutect2, pindel, varscan2
- RASL10B | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZFP36L1 | c.732dup p.D245Rfs*5 | Frame Shift Ins (INS) | VAF 55/177 reads (31%) | called by mutect2, pindel, varscan2
- ADPRS | c.513G>A p.Q171= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV52882233; called by muse, mutect2, varscan2
- CCNP | c.207G>C p.L69= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV55687285; called by muse, mutect2, varscan2
- CLDN7 | c.120C>T p.I40= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV63040284; called by muse, mutect2, varscan2
- COL11A1 | c.1695C>T p.G565= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV62198422; called by muse, mutect2, varscan2
- CPSF3 | c.624G>A p.G208= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs554338304, COSV53012062; called by muse, mutect2, varscan2
- CYP2S1 | c.520C>T p.L174= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as COSV59507346; called by muse, mutect2, varscan2
- EMSY | c.306G>A p.L102= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV58266186; called by muse, mutect2, varscan2
- GLI4 | c.660C>T p.F220= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs765748437, COSV60682881; called by muse, mutect2, varscan2
- HCLS1 | c.1359C>T p.D453= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs148435056; called by muse, mutect2, varscan2
- IWS1 | c.429A>T p.A143= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV54872015; called by muse, mutect2, varscan2
- KCNRG | c.618C>T p.N206= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs777399450, COSV57250223; called by muse, mutect2, varscan2
- KIF17 | c.1191G>A p.V397= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV56122693; called by muse, mutect2, varscan2
- MAGEC2 | c.933G>A p.K311= | Silent (SNP) | VAF 38/46 reads (83%) | catalogued as rs758440127, COSV56001307; called by muse, mutect2, varscan2
- MEI1 | c.3135C>A p.L1045= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV55908097; called by muse, mutect2, varscan2
- MYOM2 | c.3492C>G p.L1164= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs757162040, COSV50777328; called by muse, mutect2, varscan2
- NLRP4 | c.2118C>G p.L706= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV56713803, COSV56723693; called by muse, mutect2, varscan2
- NT5E | c.69G>A p.A23= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV57630397; called by muse, mutect2, varscan2
- OPTC | c.349C>T p.L117= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as rs1480621750, COSV65868686; called by muse, mutect2, varscan2
- OR2M2 | c.388C>T p.L130= | Silent (SNP) | VAF 115/359 reads (32%) | catalogued as COSV100677225, COSV100677329, COSV62899446; called by muse, mutect2, varscan2
- PTPRT | c.1437G>A p.Q479= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as rs74167780, COSV62023051; called by muse, mutect2, varscan2
- RIC1 | c.2040C>T p.I680= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV52615675, COSV99316623; called by muse, mutect2
- RYR1 | c.7047C>T p.N2349= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs149295336; called by muse, mutect2, varscan2
- SEPTIN4 | c.1194G>C p.V398= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV57899710; called by muse, mutect2, varscan2
- SLC38A7 | c.759C>T p.F253= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as rs769215514, COSV54704877; called by muse, mutect2, varscan2
- SPAG9 | c.399G>A p.L133= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as COSV56244229; called by muse, mutect2, varscan2
- SRBD1 | c.2973C>T p.L991= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs764591251, COSV55398567; called by muse, mutect2, varscan2
- TEC | c.1644C>T p.V548= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV51919816; called by muse, mutect2, varscan2
- TPSD1 | c.165G>C p.L55= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as rs781102187, COSV52978651; called by muse, mutect2, varscan2
- UMODL1 | c.2370G>C p.R790= (on ENST00000408910 / NM_001004416.2; = p.R918= on NM_173568.3) | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV68571068; called by muse, mutect2, varscan2
- VANGL2 | c.1389G>A p.V463= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV63605520; called by muse, mutect2, varscan2
- ZFHX3 | c.10677G>C p.T3559= | Silent (SNP) | VAF 70/194 reads (36%) | catalogued as rs370016565, COSV51736846; called by muse, mutect2, varscan2
- ZNF296 | c.1362C>T p.F454= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs776455930, COSV55519476; called by muse, mutect2, varscan2
- ELL | c.-1G>A | 5'UTR (SNP) | VAF 15/29 reads (52%) | catalogued as rs1398324371, COSV99442618; called by muse, mutect2, varscan2
- FGFR3 | c.*108C>T | 3'UTR (SNP) | VAF 48/63 reads (76%) | catalogued as CM084804, COSV53420509, COSV53421017; called by muse, mutect2, varscan2
